Somatic mutation profile of tumor specimen TCGA-05-4425-01A (aliquot TCGA-05-4425-01A-01D-1753-08) from TCGA case TCGA-05-4425, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.9 years (25,902 days).
Specimen TCGA-05-4425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5befb51-702c-4e71-ba8b-9f9cb04ae9c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4425-10A (Blood Derived Normal), aliquot TCGA-05-4425-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b893e93-dd75-4593-b1b3-336bcebb5bfd

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDOA | c.437G>A p.R146H (on ENST00000642816 / NM_001243177.4; = p.R92H on NM_184041.5) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs747482925, COSV100581957, COSV57633570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1A | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as COSV61370633, COSV99055302; called by muse, mutect2, varscan2
- ASTN2 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs182920283; called by muse, varscan2
- ATAD2B | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV99477126; called by muse, mutect2
- BSN | c.6137G>A p.R2046H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748620628, COSV56514874, COSV56515103; called by muse, mutect2, varscan2
- CAMK1 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.941); catalogued as COSV99844623; called by muse, mutect2, varscan2
- CCNQ | c.454del p.L152Sfs*5 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV52345301, COSV99367983; called by mutect2, pindel
- COL6A3 | c.1496T>C p.F499S | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99796528; called by muse, mutect2, varscan2
- DST | c.17705A>G p.E5902G (on ENST00000361203 / NM_001374722.1; = p.E3599G on NM_015548.5) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99752322; called by muse, mutect2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 14/71 reads (20%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- EYA2 | c.1298A>G p.N433S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1381960843, COSV100426556; called by muse, mutect2
- FSHR | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs372147824; called by muse, mutect2, varscan2
- GRIN2A | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.183); catalogued as rs768469157, COSV100408696, COSV58045915; called by muse, mutect2, varscan2
- LRP1 | c.4657T>G p.C1553G | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99674862; called by muse, mutect2, varscan2
- MPP5 | c.154C>G p.R52G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as COSV55533014, COSV99906799; called by muse, mutect2, varscan2
- NDST3 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs150758016; called by muse, mutect2, varscan2
- NECAB2 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100533866; called by mutect2, varscan2
- NELL2 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100418950, COSV61584038; called by muse, mutect2, varscan2
- PPP1R1B | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV99566070; called by muse, mutect2, varscan2
- PROKR1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773530836, COSV100375318; called by muse, mutect2, varscan2
- SNX29 | c.2372G>T p.R791L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100027545; called by muse, mutect2
- TBC1D17 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.811); catalogued as COSV99680470; called by muse, mutect2, varscan2
- THBS1 | c.1553T>G p.L518R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.896); catalogued as rs749866851, COSV99527651; called by muse, mutect2, varscan2
- TMTC1 | c.2148G>C p.Q716H (on ENST00000539277 / NM_001193451.2; = p.Q608H on NM_175861.3) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV99758976; called by muse, mutect2, varscan2
- TUBB4B | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV100457740; called by muse, mutect2, varscan2
- UNC93B1 | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV99916269; called by muse, mutect2, varscan2
- VEPH1 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100747419, COSV100747917; called by muse, mutect2, varscan2
- VPS13B | c.4654A>G p.S1552G | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100661062; called by muse, mutect2, varscan2
- YEATS2 | c.3226G>C p.V1076L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100527558; called by muse, mutect2, varscan2
- CUBN | c.4928A>G p.N1643S | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2
- NLRX1 | c.1513dup p.Y505Lfs*20 | Frame Shift Ins (INS) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- SETD2 | c.4953dup p.T1652Yfs*14 | Frame Shift Ins (INS) | VAF 44/179 reads (25%) | called by mutect2, pindel, varscan2
- ADCY5 | c.2673C>T p.G891= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs776048153, COSV59197988; called by muse, mutect2, varscan2
- BOC | c.1854C>T p.S618= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs760500732, COSV56355511; called by muse, mutect2, varscan2
- CHD7 | c.6372C>T p.F2124= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101418047; called by muse, mutect2, varscan2
- COL5A3 | c.4026G>A p.T1342= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1350479576, COSV99318350; called by muse, mutect2
- CPPED1 | c.651C>T p.D217= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as rs1475932687, COSV55495700; called by muse, mutect2, varscan2
- DHX58 | c.1341C>T p.I447= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99288071; called by muse, mutect2, varscan2
- DNAH3 | c.7359C>T p.Y2453= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs771844759, COSV54523858; called by muse, mutect2, varscan2
- ERN2 | c.693C>A p.G231= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs1018209888, COSV99890808; called by muse, mutect2, varscan2
- TTN | c.68877C>T p.G22959= (on ENST00000591111; = p.G15535= on NM_003319.4) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100598880; called by muse, mutect2, varscan2
- USP20 | c.2094C>T p.S698= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100204095; called by muse, mutect2, varscan2
- C9orf106 | n.647T>C | RNA (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
